Surgical pathology report (de-identified scan), TCGA case TCGA-4Z-AA83, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-4Z-AA83-01A (Primary Tumor).

ICD-O-3
Carcinoma, urothelial
papillary 8130/3
Site Bladder NOS C67.9
J23/18/14

Collect date:
(MM/DD/YYYY)

PATHOLOGY REPORT:

PRIMARY SITE: Bladder

Product of cystectomy:

Papillary urothelial carcinoma of high grade infiltrating the corion and focally the detrusor muscle with free surgical margins.

Absence of angiolymphatic, sanguineous and perineural invasions.

Margin of right and left ureters free of neoplasia.

Urethral margin free of neoplasia.

Prostate free of cancer.

Right and left seminal vesicles free of neoplasia.

Right and left vas deferens free of neoplasia.

Lymph nodes free of tumor: (0/2)

Left pelvic lymph nodes:

Absence of neoplasia: (0/13)

Right pelvic lymph nodes:

Absence of neoplasia: (0/4)

External left iliac lymph nodes:

Absence of neoplasia: (0/3)

Right iliac lymph nodes:

Absence of neoplasia: (0/6)

Right common lymph nodes:

Absence of neoplasia: (0/3)

Criteria	hw 12/30/13	Yes	No

Source: NCI Genomic Data Commons file 28efbb38-4a95-4702-b131-e3c9a309a5ca (TCGA-4Z-AA83.C177DD54-DBBB-44F1-9476-D5D1E543DE04.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).